Somatic mutation profile of tumor specimen TCGA-NH-A8F7-06A (aliquot TCGA-NH-A8F7-06A-31D-A40P-10) from TCGA case TCGA-NH-A8F7, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.5 years (19,535 days).
Specimen TCGA-NH-A8F7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0f0b00c-1037-452f-92aa-2ccd1aedea08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A8F7-10A (Blood Derived Normal), aliquot TCGA-NH-A8F7-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/578752f1-f677-4bd5-ae35-81fe82dce057

The open-access MAF lists 121 somatic variants for this specimen: 82 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 37, Frame Shift Del 8, Nonsense Mutation 5, Frame Shift Ins 3, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 33/56 reads (59%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 245/516 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.2642C>A p.A881E | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100741879; called by muse, mutect2, varscan2
- ACTRT1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 112/130 reads (86%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1030175845, COSV100947757; called by muse, mutect2, varscan2
- ADAMTS3 | c.2737G>T p.E913* | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV54402630, COSV99711985; called by muse, mutect2, varscan2
- ADAMTS5 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs150380425; called by muse, mutect2, varscan2
- ADGRV1 | c.12211C>T p.R4071* | Nonsense Mutation (SNP) | VAF 51/79 reads (65%) | catalogued as rs1163308590, COSV67993770; called by muse, mutect2, varscan2
- AGRN | c.3112G>A p.V1038M | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs765711667, COSV101039061; called by muse, mutect2, varscan2
- ANLN | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 102/702 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV99732812; called by muse, mutect2, varscan2
- ATP2A2 | c.2839C>T p.L947F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100428887; called by muse, mutect2, varscan2
- C4BPA | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs867500835, CM132732, COSV65536149; called by muse, mutect2, varscan2
- CABYR | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs753369114, COSV100510174; called by muse, mutect2, varscan2
- CCDC39 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs959183002, COSV99870582; called by muse, mutect2, varscan2
- CEACAM21 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV51816430; called by muse, mutect2, varscan2
- CHAT | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100340846; called by muse, mutect2, varscan2
- CHD4 | c.1847A>G p.N616S (on ENST00000357008 / NM_001363606.2; = p.N629S on NM_001273.5) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV58910288; called by muse, mutect2, varscan2
- CNGA2 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100323934; called by muse, mutect2, varscan2
- COL4A1 | c.4081C>A p.L1361I | Missense Mutation (SNP) | VAF 83/128 reads (65%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.714); catalogued as COSV65429080; called by muse, mutect2, varscan2
- CRMP1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100272332; called by muse, mutect2
- CTSO | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as COSV101467884; called by muse, mutect2, varscan2
- CTU1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV70292826; called by muse, mutect2
- DAB2IP | c.2896C>T p.R966C (on ENST00000408936; = p.R938C on NM_032552.3) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs371407818, COSV99405523, COSV99406295; called by muse, mutect2, varscan2
- DTNBP1 | c.955G>C p.V319L | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100161132; called by muse, mutect2, varscan2
- EHF | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV99141045; called by muse, mutect2, varscan2
- GABBR1 | c.448T>A p.W150R | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100590042; called by muse, mutect2, varscan2
- GRAMD4 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100730645; called by muse, mutect2, varscan2
- GRIA2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371939918; called by muse, mutect2, varscan2
- GRN | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99275097; called by muse, mutect2, varscan2
- HECTD2 | c.2051C>T p.T684M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV99978958; called by muse, mutect2, varscan2
- HYDIN | c.7513C>T p.R2505C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368364639; called by muse, mutect2, varscan2
- IL1R1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99292883; called by muse, mutect2, varscan2
- JHY | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs769092607, COSV57073362; called by muse, mutect2, varscan2
- KIF26A | c.3383C>T p.T1128M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.302); catalogued as rs199867714, COSV100181541; called by muse, mutect2, varscan2
- LAMA5 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99438206; called by muse, mutect2, varscan2
- LIPH | c.6G>C p.L2F | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56185890; called by muse, mutect2, varscan2
- LRFN5 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99985373; called by muse, mutect2, varscan2
- LY96 | c.22dup p.S8Ffs*10 | Frame Shift Ins (INS) | VAF 51/95 reads (54%) | catalogued as rs1234074626; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MYH15 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV56305690, COSV99844262; called by muse, mutect2, varscan2
- MYH7 | c.4985G>A p.R1662H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs370328209, CM115875, CM146976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCSTN | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs200672191, COSV54189160; called by muse, mutect2, varscan2
- NID1 | c.2367C>A p.C789* | Nonsense Mutation (SNP) | VAF 57/102 reads (56%) | catalogued as COSV99938280; called by muse, mutect2, varscan2
- NINL | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 114/151 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748441660, COSV54004915; called by muse, mutect2, varscan2
- NLRP7 | c.2155G>A p.A719T (on ENST00000340844 / NM_206828.3; = p.A691T on NM_139176.3) | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.406); catalogued as rs764145628, COSV60181539; called by muse, mutect2, varscan2
- NRXN1 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68045067; called by muse, mutect2, varscan2
- NTF3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779157298, COSV58418345; called by muse, mutect2, varscan2
- NUFIP1 | c.1443_1444insG p.F482Vfs*7 | Frame Shift Ins (INS) | VAF 107/385 reads (28%) | catalogued as COSV100998060; called by mutect2, pindel, varscan2
- ORC4 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV51577001; called by muse, mutect2, varscan2
- PCDHA8 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 116/130 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971010; called by muse, mutect2, varscan2
- PLA2R1 | c.3500G>A p.R1167Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as rs759938799, COSV51784846; called by muse, mutect2, varscan2
- POLR3B | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs767558518, COSV99943846; called by muse, mutect2, varscan2
- PRKCG | c.932T>G p.L311W | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV99669513; called by muse, mutect2, varscan2
- PTPRC | c.1974G>A p.Q658= | Splice Region (SNP) | VAF 71/114 reads (62%) | catalogued as COSV100723152, COSV100723161; called by muse, mutect2, varscan2
- RBP3 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs782172169; called by muse, mutect2, varscan2
- RTL3 | c.521A>T p.Q174L | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100330078; called by muse, mutect2, varscan2
- SCN4A | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs749841448, COSV71127756; called by muse, mutect2, varscan2
- SEPTIN14 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV101193432; called by muse, mutect2, varscan2
- SIMC1 | c.2459A>C p.K820T (on ENST00000443967 / NM_001308196.1; = p.K405T on NM_198567.5) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as COSV53800067; called by muse, mutect2
- SLITRK6 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761115685, COSV101233294, COSV68391387; called by muse, mutect2, varscan2
- SNX2 | c.762G>C p.Q254H | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV101075829; called by muse, mutect2, varscan2
- SNX29 | c.1697T>G p.V566G | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100030098; called by muse, mutect2, varscan2
- SPANXD | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 328/1393 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs373261190, COSV65152935; called by muse, mutect2, varscan2
- SPRR3 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99768763; called by muse, mutect2, varscan2
- SYMPK | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99842095; called by muse, mutect2, varscan2
- TBX20 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs200704561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM260 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs747674520, COSV55098373; called by muse, mutect2, varscan2
- TRAP1 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs141361125, COSV55918289; called by muse, mutect2, varscan2
- TRIM50 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 131/332 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs201629397, COSV52722924; called by muse, mutect2, varscan2
- TTLL10 | c.572C>T p.T191M (on ENST00000379289 / NM_001130045.2; = p.T118M on NM_153254.3) | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs775102650, COSV101016904; called by muse, mutect2, varscan2
- TULP1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs139588263; called by muse, mutect2, varscan2
- ULK4 | c.2738C>A p.A913E | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs762525218, COSV100095173; called by muse, mutect2, varscan2
- UNC45B | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs1340474258, COSV99269216; called by muse, mutect2, varscan2
- ZNF793 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs574965041, COSV71324958; called by muse, mutect2, varscan2
- APC | c.4311_4314del p.K1437Nfs*35 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | called by mutect2, pindel, varscan2
- CEP57 | c.1409_1418del p.P470Qfs*9 | Frame Shift Del (DEL) | VAF 143/316 reads (45%) | called by mutect2, pindel, varscan2
- DNAJC28 | c.951T>G p.I317M | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EHD2 | c.1235dup p.A413Rfs*3 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- HSPG2 | c.10361del p.Q3454Rfs*67 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- IARS1 | c.451del p.L151Cfs*26 | Frame Shift Del (DEL) | VAF 119/360 reads (33%) | called by mutect2, pindel, varscan2
- NVL | c.2096_2103del p.V699Gfs*24 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- PLK4 | c.1550del p.N517Mfs*21 | Frame Shift Del (DEL) | VAF 82/234 reads (35%) | called by mutect2, pindel, varscan2
- PROS1 | c.319del p.Y107Ifs*4 | Frame Shift Del (DEL) | VAF 198/531 reads (37%) | called by mutect2, pindel, varscan2
- AC005833.1 | c.1482G>A p.E494= | Silent (SNP) | VAF 66/196 reads (34%) | catalogued as rs145999043; called by muse, mutect2, varscan2
- CAPSL | c.36G>A p.A12= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs373881430; called by muse, mutect2, varscan2
- CLDN11 | c.507C>T p.L169= | Silent (SNP) | VAF 66/153 reads (43%) | catalogued as rs764051667, COSV50355404; called by muse, mutect2, varscan2
- CRMP1 | c.1206C>T p.A402= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs540841995, COSV100272275, COSV61478148; called by muse, mutect2, varscan2
- DSCAM | c.1137C>T p.D379= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs755469143, COSV68020597; called by muse, mutect2, varscan2
- FLNC | c.7863G>A p.R2621= | Silent (SNP) | VAF 16/339 reads (5%) | catalogued as COSV99972549; called by muse, mutect2
- GFRA3 | c.762C>T p.L254= | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as COSV99218543; called by muse, mutect2, varscan2
- GNB2 | c.669C>T p.I223= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs371447650; called by muse, mutect2, varscan2
- GRB7 | c.897C>T p.F299= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs769909695, COSV100485370; called by muse, mutect2, varscan2
- GRIA4 | c.1740C>T p.D580= | Silent (SNP) | VAF 96/184 reads (52%) | catalogued as rs542853979, COSV56922996; called by muse, mutect2, varscan2
- GRIN2A | c.3363T>C p.D1121= | Silent (SNP) | VAF 48/157 reads (31%) | catalogued as COSV100410983; called by muse, mutect2, varscan2
- GUCY1B1 | c.1434G>A p.K478= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs776167443, COSV100025912; called by muse, mutect2, varscan2
- HS3ST3A1 | c.501G>A p.A167= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs769643418, COSV99404504; called by mutect2, varscan2
- KCNG2 | c.294G>A p.A98= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1165271224, COSV60270747; called by muse, mutect2, varscan2
- KRTAP6-2 | c.6C>T p.C2= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs201729927, COSV58182857; called by muse, mutect2, varscan2
- LDHA | c.339C>T p.N113= | Silent (SNP) | VAF 39/64 reads (61%) | catalogued as rs761698693, COSV57042505; called by muse, mutect2, varscan2
- LILRA4 | c.987G>A p.Q329= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV99393372; called by muse, mutect2, varscan2
- MX1 | c.1332G>A p.E444= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1347868105, COSV99912826; called by muse, mutect2, varscan2
- MYH9 | c.1614C>T p.T538= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as rs756460248, COSV99339801; called by muse, mutect2, varscan2
- PCDHGB7 | c.498G>A p.S166= | Silent (SNP) | VAF 56/107 reads (52%) | catalogued as COSV99546436; called by muse, mutect2, varscan2
- PCYOX1L | c.483C>T p.Y161= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99199281; called by muse, mutect2, varscan2
- PLCD1 | c.1773C>T p.G591= | Silent (SNP) | VAF 57/68 reads (84%) | catalogued as COSV99379251; called by muse, mutect2, varscan2
- PPME1 | c.294G>A p.A98= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1209005176, COSV100076683; called by muse, mutect2, varscan2
- PRKCA | c.1203G>A p.T401= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs370620237, COSV52597369; called by muse, mutect2, varscan2
- PRLHR | c.1095C>T p.T365= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV53305072; called by muse, mutect2, varscan2
- SF3B4 | c.894G>A p.P298= | Silent (SNP) | VAF 93/155 reads (60%) | catalogued as rs782759025, COSV99641416; called by muse, mutect2, varscan2
- SH3D21 | c.1812G>A p.A604= (on ENST00000453908 / NM_001162530.2; = p.A493= on NM_024676.5) | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs997016807, COSV99584242; called by muse, mutect2, varscan2
- SLC6A17 | c.150G>A p.A50= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs199862853; called by muse, mutect2, varscan2
- SYNPO2 | c.1989G>A p.S663= | Silent (SNP) | VAF 80/167 reads (48%) | catalogued as rs754544777, COSV61116696; called by muse, mutect2, varscan2
- TAS1R2 | c.690C>T p.R230= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs753805144, COSV100946367; called by muse, mutect2, varscan2
- TECTA | c.2592C>T p.N864= | Silent (SNP) | VAF 137/268 reads (51%) | catalogued as rs377433816, CM054139; called by muse, mutect2, varscan2
- TRO | c.1860C>A p.V620= | Silent (SNP) | VAF 49/67 reads (73%) | catalogued as COSV99437277; called by muse, mutect2, varscan2
- TRRAP | c.6759G>A p.G2253= (on ENST00000359863 / NM_001244580.1; = p.G2235= on NM_003496.3) | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV100722920; called by muse, mutect2, varscan2
- UNC13A | c.2013G>A p.T671= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV53209496; called by muse, mutect2, varscan2
- USP38 | c.1041G>A p.A347= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs141985651, COSV61025232; called by muse, mutect2
- VWA8 | c.2403C>T p.P801= | Silent (SNP) | VAF 61/195 reads (31%) | catalogued as COSV99865099; called by muse, mutect2, varscan2
- ZNF230 | c.390A>G p.L130= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as COSV71273691; called by muse, mutect2
- SSPOP | n.1322C>G | RNA (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100022979, COSV50489430; called by muse, mutect2, varscan2
- UMODL1 | c.1520-1211G>A | Intron (SNP) | VAF 48/105 reads (46%) | catalogued as rs762237213, COSV100210865; called by muse, mutect2, varscan2
